Somatic mutation profile of tumor specimen TCGA-Z2-AA3S-06A (aliquot TCGA-Z2-AA3S-06A-11D-A397-08) from TCGA case TCGA-Z2-AA3S, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.6 years (23,946 days).
Specimen TCGA-Z2-AA3S-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a820cbe-62fd-4e3f-96c3-4a8346116f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z2-AA3S-10A (Blood Derived Normal), aliquot TCGA-Z2-AA3S-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05c1300e-51e0-4651-99e6-2502d8d6f171

The open-access MAF lists 257 somatic variants for this specimen: 163 protein-altering or splice-affecting, 87 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 87, Nonsense Mutation 10, Intron 4, Splice Site 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.63); catalogued as rs587784403, CM096582, COSV100447086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100528579; called by muse, mutect2, varscan2
- AAGAB | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs779782680, COSV56016015; called by muse, mutect2, varscan2
- AC126283.2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67097947; called by muse, mutect2, varscan2
- ADGRV1 | c.3118A>G p.T1040A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV101315550; called by muse, mutect2, varscan2
- AK8 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049750; called by muse, mutect2, varscan2
- AMIGO2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.179); catalogued as COSV56973136, COSV56973624; called by muse, mutect2, varscan2
- ARHGEF28 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99708355; called by muse, mutect2, varscan2
- ARID4A | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100794071; called by muse, mutect2, varscan2
- ATAD5 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1161951900, COSV100429718; called by muse, mutect2, varscan2
- ATP1A3 | c.271G>A p.E91K (on ENST00000545399 / NM_001256214.2; = p.E78K on NM_152296.5) | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100132034; called by muse, mutect2, varscan2
- B4GALNT2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489404226, COSV55928231; called by muse, mutect2, varscan2
- BMP7 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV101215593; called by muse, mutect2, varscan2
- C12orf56 | c.1174G>A p.D392N (on ENST00000543942 / NM_001170633.2; = p.D232N on NM_001099676.3) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs866405788, COSV100399092; called by muse, mutect2, varscan2
- C1orf158 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV55346323, COSV99847215; called by muse, mutect2, varscan2
- C7orf25 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100623609; called by muse, mutect2, varscan2
- C8B | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV64777473; called by muse, mutect2, varscan2
- CARD11 | c.2209C>T p.H737Y | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100829099; called by muse, mutect2, varscan2
- CARD11 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV62717069; called by muse, mutect2, varscan2
- CARD6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.413); catalogued as COSV99620391; called by muse, mutect2, varscan2
- CCDC144A | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV100501965; called by muse, mutect2, varscan2
- CCDC87 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as COSV100039790; called by muse, mutect2, varscan2
- CCN6 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 28/36 reads (78%) | catalogued as COSV100036911; called by muse, mutect2, varscan2
- CDC27 | c.2292G>A p.M764I | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV50643474; called by muse, mutect2, varscan2
- CENPJ | c.3742C>T p.P1248S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99692415; called by muse, mutect2, varscan2
- CEP89 | c.1690A>C p.K564Q | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV99993162; called by muse, mutect2, varscan2
- CFAP61 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1332120561, COSV99843607; called by muse, mutect2, varscan2
- CLEC16A | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as COSV55489231; called by muse, mutect2, varscan2
- CLUL1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100620926; called by muse, mutect2, varscan2
- CMTR2 | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57604366; called by muse, mutect2
- CNTNAP2 | c.1490T>A p.F497Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100663511; called by muse, mutect2, varscan2
- COL19A1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV59577931; called by muse, mutect2, varscan2
- COL2A1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100475723; called by muse, mutect2, varscan2
- COL8A2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246579875, COSV57440741, COSV57441030; called by muse, mutect2, varscan2
- CSDE1 | c.577A>T p.M193L (on ENST00000358528 / NM_001007553.3; = p.M162L on NM_007158.6) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1465020685, COSV99794230; called by muse, mutect2, varscan2
- DAB1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100139585; called by muse, mutect2, varscan2
- DBF4B | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100154324; called by muse, mutect2, varscan2
- DCDC1 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100662834; called by muse, mutect2, varscan2
- DDHD2 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101240533; called by muse, mutect2, varscan2
- DGCR8 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100707834; called by muse, mutect2, varscan2
- DNAH5 | c.12379C>T p.R4127C | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148696723; ClinVar: uncertain significance; called by muse, mutect2
- DNAH5 | c.9139G>A p.E3047K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54206416; called by muse, mutect2, varscan2
- DRD5 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58579458; called by muse, mutect2, varscan2
- EIF4G3 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV51675180; called by muse, mutect2, varscan2
- ELAVL3 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs143463189; called by muse, mutect2, varscan2
- ERG | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV99901317, COSV99902276; called by muse, mutect2, varscan2
- ERO1B | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100523937; called by muse, mutect2, varscan2
- ETV4 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99291976; called by muse, mutect2, varscan2
- FAM13C | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as rs761467733, COSV99513206; called by muse, mutect2, varscan2
- FAM149A | c.1906G>A p.G636R (on ENST00000356371 / NM_001367768.2; = p.G345R on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1485352979, COSV99906383; called by muse, mutect2, varscan2
- FAM71B | c.1241G>C p.S414T | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV100261904; called by muse, mutect2, varscan2
- FAT1 | c.11405G>A p.G3802E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV101499133; called by muse, mutect2, varscan2
- FAT3 | c.6121C>T p.P2041S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV99962786; called by muse, mutect2, varscan2
- FCRL3 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100942917; called by muse, mutect2, varscan2
- FGD2 | c.301-1G>A p.X101_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99235916; called by muse, mutect2
- FLG | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1194239166, COSV64239899; called by muse, mutect2, varscan2
- FLRT2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs1219460941, COSV58136260; called by muse, mutect2, varscan2
- FOXI2 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1379782406, COSV100510948, COSV59094401; called by muse, mutect2
- FUT3 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs749102650, COSV54610378; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FYB1 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60942234; called by muse, mutect2, varscan2
- FYB2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as COSV100599285; called by muse, mutect2, varscan2
- GABRG1 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.726); catalogued as COSV99777518, COSV99778517; called by muse, mutect2, varscan2
- GNAT1 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.43); catalogued as COSV99137245; called by muse, mutect2, varscan2
- GRIP1 | c.2036A>C p.Y679S (on ENST00000359742 / NM_001379345.1; = p.Y627S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV99668337; called by muse, mutect2, varscan2
- GRM6 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99179472; called by muse, mutect2, varscan2
- GTPBP3 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1403421596, COSV100258720; called by muse, mutect2, varscan2
- HCN4 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV99983382; called by muse, mutect2, varscan2
- HECTD4 | c.9590C>T p.S3197F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1279215454, COSV101106834; called by muse, mutect2, varscan2
- HEPH | c.364C>T p.P122S (on ENST00000343002; = p.P176S on NM_138737.5) | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as rs760595099, COSV100294255; called by muse, mutect2, varscan2
- HFE | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319320999, COSV100352514; called by muse, mutect2, varscan2
- HSF5 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV100089906; called by muse, mutect2, varscan2
- IGF2BP1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs751061699, COSV99288337; called by muse, mutect2, varscan2
- ITGAD | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs199833797; called by muse, mutect2, varscan2
- KCNJ15 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157297131, COSV100154056; called by muse, mutect2, varscan2
- KDR | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs748503151, COSV99816874; called by muse, mutect2, varscan2
- KHDC4 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV100850776; called by muse, mutect2, varscan2
- KIAA1549L | c.2797C>T p.P933S (on ENST00000321505; = p.P1230S on NM_012194.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); catalogued as COSV55775686; called by muse, mutect2, varscan2
- KIAA1549L | c.2798C>T p.P933L (on ENST00000321505; = p.P1230L on NM_012194.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.104); catalogued as rs1368071427, COSV99682756; called by muse, mutect2, varscan2
- KIAA1614 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs774926889, COSV100851160; called by muse, mutect2, varscan2
- KIF1A | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV100239998; called by muse, mutect2, varscan2
- KLK4 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs747268930, COSV100133526, COSV60675886; called by muse, mutect2, varscan2
- KRT16 | c.998T>G p.V333G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100052841; called by muse, mutect2, varscan2
- LAMC2 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs773517261, COSV99917147; called by muse, varscan2
- LCK | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV100287475; called by muse, mutect2, varscan2
- LNPEP | c.3048G>C p.K1016N | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99183485; called by muse, mutect2, varscan2
- LPA | c.4189C>T p.R1397* | Nonsense Mutation (SNP) | VAF 56/145 reads (39%) | catalogued as rs200154828, COSV60299838; called by muse, mutect2, varscan2
- LRBA | c.5554G>A p.E1852K | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100841031; called by muse, mutect2, varscan2
- LRRC41 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1164186138, COSV58439487; called by muse, mutect2, varscan2
- LRRC46 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs144936742; called by muse, mutect2, varscan2
- LUM | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.294); catalogued as COSV57127837; called by muse, mutect2, varscan2
- MAS1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53122066, COSV99396803; called by muse, mutect2, varscan2
- MCRS1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1359774691, COSV99234831; called by muse, mutect2, varscan2
- MEGF8 | c.1897T>A p.W633R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99234767; called by muse, mutect2, varscan2
- MKRN2 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 108/127 reads (85%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99312017; called by muse, mutect2, varscan2
- MPP2 | c.1708G>A p.V570M (on ENST00000461854 / NM_001278372.2; = p.V546M on NM_005374.5) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99290004; called by muse, mutect2, varscan2
- MS4A14 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100280114; called by muse, mutect2, varscan2
- MTCP1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV100749855; called by muse, mutect2, varscan2
- MUC16 | c.31001C>T p.S10334F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as COSV67457269; called by muse, mutect2, varscan2
- MYH8 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745600958, COSV101238287; called by muse, mutect2, varscan2
- MYT1L | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs200175227, COSV101219201; called by muse, mutect2, varscan2
- NLGN4X | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320231, COSV99323981; called by muse, mutect2, varscan2
- NLRP14 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866354589, COSV55067734; called by muse, mutect2, varscan2
- NOS1AP | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as rs746933296, COSV100722905; called by muse, mutect2, varscan2
- NUAK1 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1157642732, COSV54608178; called by muse, mutect2, varscan2
- OR11H12 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV101612462; called by muse, mutect2, varscan2
- OR51B5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56175631; called by muse, mutect2, varscan2
- OR7D4 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100432616; called by muse, mutect2, varscan2
- PANX3 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374367993; called by muse, mutect2, varscan2
- PCDHB8 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs782113809, COSV99176091; called by muse, mutect2, varscan2
- PDE1A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs145482728, COSV59527650; called by muse, mutect2, varscan2
- PDGFRB | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs751904503, COSV55800810; called by muse, mutect2, varscan2
- PDZK1IP1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.156); catalogued as rs770763970, COSV53743743; called by muse, mutect2, varscan2
- PHF10 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100199784; called by muse, mutect2, varscan2
- PHLPP1 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV99407032, COSV99407535; called by muse, mutect2, varscan2
- PIDD1 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1270819352, COSV100204116; called by muse, mutect2, varscan2
- PIGQ | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99215789; called by muse, mutect2, varscan2
- POLR3E | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 104/271 reads (38%) | catalogued as COSV100241951; called by muse, mutect2, varscan2
- POMGNT2 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as rs1185015027, COSV100767928; called by muse, mutect2, varscan2
- PRDM9 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV57006173, COSV99690394; called by muse, mutect2, varscan2
- PROX2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV71520032; called by muse, mutect2, varscan2
- PSG11 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 77/171 reads (45%) | catalogued as rs1441148174, COSV60455181; called by muse, mutect2, varscan2
- PTCHD3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.042); catalogued as COSV101438860; called by muse, mutect2, varscan2
- RBM23 | c.577C>T p.R193C (on ENST00000359890 / NM_001077351.2; = p.R177C on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771869504, COSV100321316; called by muse, mutect2, varscan2
- RFC4 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56215765, COSV99961052; called by muse, mutect2, varscan2
- RIMS3 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs765042870, COSV101013297; called by muse, mutect2, varscan2
- RPL5 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100240286; called by muse, mutect2, varscan2
- S1PR1 | c.1109A>C p.E370A | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100541497; called by muse, mutect2, varscan2
- SALL2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100444181; called by muse, mutect2, varscan2
- SCN10A | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs866716316, COSV71860652; called by muse, mutect2, varscan2
- SCN1A | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113289, COSV100319538, COSV100319545; called by muse, mutect2, varscan2
- SCN5A | c.4924G>A p.G1642R (on ENST00000333535 / NM_198056.3; = p.G1641R on NM_000335.5) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100346814; called by muse, mutect2, varscan2
- SLFN11 | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57700056; called by muse, mutect2, varscan2
- SNAP91 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52115352; called by muse, mutect2, varscan2
- SORL1 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1297854061, COSV52764848, COSV99493066; called by muse, mutect2
- ST7 | c.1399G>T p.E467* (on ENST00000265437 / NM_021908.3; = p.E444* on NM_018412.4) | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | catalogued as COSV55387568, COSV99621286; called by muse, mutect2, varscan2
- SUPT3H | c.254G>A p.G85E (on ENST00000371460 / NM_181356.3; = p.G74E on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs751408646, COSV100176357; called by muse, mutect2, varscan2
- SVIL | c.5438A>C p.Y1813S (on ENST00000355867 / NM_021738.3; = p.Y1387S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV100881017; called by muse, mutect2, varscan2
- SYCP2 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100698038; called by muse, mutect2, varscan2
- SYN2 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV70285122; called by muse, mutect2, varscan2
- SYN3 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248504; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 87/104 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by muse, mutect2, varscan2
- TNC | c.2725A>T p.I909F | Missense Mutation (SNP) | VAF 122/158 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100405105; called by muse, mutect2, varscan2
- TNFSF10 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as rs145536359, COSV53842551; called by muse, mutect2, varscan2
- TNN | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53437781; called by muse, mutect2, varscan2
- TNN | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV99511252; called by muse, mutect2, varscan2
- TOP2A | c.1822T>C p.W608R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV101396083; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1228+1G>C p.X410_splice | Splice Site (SNP) | VAF 26/53 reads (49%) | catalogued as rs375800644, COSV100389662, COSV60676165; called by muse, mutect2, varscan2
- TRIM43 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1296674028, COSV99719874; called by muse, mutect2, varscan2
- TSHZ3 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.994); catalogued as COSV53682306, COSV99550823; called by muse, mutect2, varscan2
- TXNDC11 | c.2695G>A p.E899K (on ENST00000356957 / NM_001303447.2; = p.E872K on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV51602865; called by muse, mutect2, varscan2
- ZNF181 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1437627618, COSV101106201; called by muse, mutect2, varscan2
- ZNF211 | c.1046C>T p.S349F (on ENST00000347302 / NM_198855.4; = p.S362F on NM_006385.5) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99559996, COSV99560102; called by muse, mutect2, varscan2
- ZNF318 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as rs141536231, COSV58937905; called by muse, mutect2, varscan2
- ZNF330 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs866613410, COSV99522432; called by muse, mutect2, varscan2
- ZNF521 | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.23); catalogued as COSV100831546; called by muse, mutect2, varscan2
- ZNF536 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1568436588, COSV100834805; called by muse, mutect2, varscan2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF610 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV58344115, COSV58345261; called by muse, mutect2, varscan2
- ZNF775 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100301326, COSV61613027; called by muse, mutect2, varscan2
- ZNF831 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV64040935, COSV64044718; called by muse, mutect2, varscan2
- ZNF831 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs556625329, COSV64040952; called by muse, mutect2, varscan2
- BTBD10 | c.295_296dup p.E100Lfs*65 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.72C>T p.I24= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs1259047649, COSV101315549; called by muse, mutect2, varscan2
- ADGRV1 | c.14628C>T p.V4876= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs761513059, COSV101315551; called by muse, varscan2
- AFM | c.1719C>T p.F573= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs766941334, COSV56918945; called by muse, mutect2, varscan2
- ATP10B | c.381C>T p.F127= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs190770337; called by muse, mutect2, varscan2
- ATP13A2 | c.3006C>T p.L1002= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs376802141; called by muse, mutect2, varscan2
- ATP2C2 | c.747G>A p.G249= | Silent (SNP) | VAF 39/47 reads (83%) | catalogued as rs753850251, COSV99297542; called by muse, mutect2, varscan2
- C7orf57 | c.495G>A p.K165= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1439112197, COSV100817206; called by muse, mutect2, varscan2
- CACNA1S | c.2340C>T p.F780= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV62938085; called by muse, mutect2, varscan2
- CARD11 | c.552G>A p.K184= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs769926365, COSV100712214; called by muse, mutect2, varscan2
- CDH22 | c.213G>A p.V71= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100952755; called by muse, mutect2, varscan2
- CHD7 | c.2287C>T p.L763= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV101418035; called by muse, mutect2, varscan2
- CHGB | c.1488G>A p.R496= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs747180447, COSV100972925; called by muse, mutect2, varscan2
- CHRNA1 | c.915C>T p.I305= (on ENST00000261007 / NM_001039523.3; = p.I280= on NM_000079.4) | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs754070026, COSV99650210; called by muse, mutect2, varscan2
- COL6A1 | c.174C>T p.L58= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100719988; called by muse, mutect2, varscan2
- COPZ2 | c.579G>A p.V193= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs904664144, COSV99133574; called by muse, mutect2, varscan2
- CYFIP2 | c.3453C>T p.F1151= (on ENST00000616178 / NM_001291722.2; = p.F1126= on NM_014376.4) | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100555809; called by muse, mutect2, varscan2
- DISP3 | c.3021C>T p.T1007= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs772350168, COSV99607604; called by muse, mutect2, varscan2
- DMXL1 | c.2766C>T p.I922= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs750663489, COSV100223429; called by muse, mutect2, varscan2
- DNAH3 | c.10158G>A p.K3386= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV54517230, COSV54526133; called by muse, mutect2, varscan2
- DTX3L | c.1194G>A p.E398= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as COSV99949894; called by muse, mutect2, varscan2
- ERICH3 | c.1239G>A p.R413= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV58619687; called by muse, mutect2, varscan2
- FBLIM1 | c.945G>A p.G315= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs778266963, COSV100181612; called by muse, mutect2, varscan2
- FGD6 | c.834G>A p.G278= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV59696853; called by muse, mutect2, varscan2
- GAP43 | c.327C>T p.S109= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs773971941, COSV59343857; called by muse, mutect2, varscan2
- GIMAP1 | c.381G>A p.Q127= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100211974; called by muse, mutect2, varscan2
- GREM2 | c.336G>A p.K112= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs1199051572, COSV100547329; called by muse, mutect2, varscan2
- HCN4 | c.2494C>T p.L832= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs200058167, COSV99983380; called by muse, mutect2, varscan2
- HCN4 | c.666C>T p.L222= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV99983385; called by muse, mutect2, varscan2
- HRNR | c.3417C>A p.P1139= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as COSV100913072; called by muse, varscan2
- HSD17B2 | c.417C>T p.I139= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99556460; called by muse, mutect2, varscan2
- JAKMIP2 | c.594C>T p.I198= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV99507573; called by muse, mutect2, varscan2
- KCNT2 | c.475T>C p.L159= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99651953; called by muse, mutect2, varscan2
- KIAA1549 | c.3018C>T p.F1006= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs369870112; called by muse, mutect2, varscan2
- KIF1A | c.2202G>A p.K734= | Silent (SNP) | VAF 43/53 reads (81%) | catalogued as rs1419731122, COSV100240000; called by muse, mutect2, varscan2
- LAMB3 | c.663C>T p.F221= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100620152; called by muse, mutect2, varscan2
- LRP1 | c.6960C>T p.F2320= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs760341464, COSV99674761; called by muse, mutect2, varscan2
- LRRC37A | c.2220C>T p.T740= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV100208117; called by mutect2, varscan2
- MAS1 | c.777G>A p.G259= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs750404972, COSV99396805; called by muse, mutect2, varscan2
- MEX3A | c.913C>T p.L305= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV101348921; called by muse, mutect2, varscan2
- MGAM | c.5373A>C p.T1791= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs765505057, COSV101527393; called by muse, mutect2, varscan2
- MKRN2 | c.420C>T p.P140= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as rs535538034, COSV99403041; called by muse, mutect2, varscan2
- MORC1 | c.354G>A p.T118= | Silent (SNP) | VAF 30/39 reads (77%) | catalogued as rs555321094, COSV51713642; called by muse, mutect2, varscan2
- MRTFA | c.2286C>T p.S762= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs777904504, COSV100843881; called by muse, mutect2, varscan2
- MYO5B | c.171C>T p.N57= | Silent (SNP) | VAF 81/194 reads (42%) | catalogued as rs375237075; called by muse, mutect2, varscan2
- MYOM3 | c.2868C>T p.V956= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100292577; called by muse, mutect2, varscan2
- NEXMIF | c.3078C>T p.F1026= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV50180872; called by muse, mutect2, varscan2
- NRROS | c.409C>T p.L137= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as COSV100145379; called by muse, mutect2, varscan2
- NXNL1 | c.249G>A p.T83= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs374141772, COSV57325286; called by muse, mutect2, varscan2
- NYNRIN | c.3768C>T p.I1256= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV101230521; called by muse, mutect2, varscan2
- OR10T2 | c.711C>T p.A237= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs541159829, COSV100554839; called by muse, mutect2
- OR1Q1 | c.678C>T p.L226= | Silent (SNP) | VAF 35/45 reads (78%) | catalogued as COSV99939189; called by muse, mutect2, varscan2
- OR4C3 | c.141C>T p.I47= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100167551, COSV60587955; called by muse, mutect2, varscan2
- OR4K2 | c.336C>T p.I112= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs754020790, COSV53848253; called by muse, mutect2, varscan2
- OR4S1 | c.645C>T p.S215= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs185639195, COSV100180189; called by muse, mutect2, varscan2
- OR5B12 | c.117G>A p.G39= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV56905770; called by muse, mutect2, varscan2
- PCDHB10 | c.2124C>T p.L708= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV53381343; called by muse, mutect2, varscan2
- PGK2 | c.795C>T p.I265= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as rs774299538, COSV59162610; called by muse, mutect2, varscan2
- PLA2G4F | c.2289C>T p.F763= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV51829075; called by muse, mutect2, varscan2
- PLCL2 | c.2883G>A p.L961= (on ENST00000615277 / NM_001144382.2; = p.L835= on NM_015184.5) | Silent (SNP) | VAF 88/117 reads (75%) | catalogued as COSV101196595; called by muse, mutect2, varscan2
- PLEC | c.5973C>T p.I1991= (on ENST00000322810 / NM_201380.4; = p.I1881= on NM_000445.5) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs782000075, COSV59638901; called by muse, mutect2, varscan2
- PLXNA2 | c.4419C>T p.P1473= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100885205; called by muse, mutect2, varscan2
- POLR1B | c.978C>T p.F326= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99637273; called by muse, mutect2, varscan2
- PRDM16 | c.507C>T p.L169= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs868764694, COSV99575707; called by muse, mutect2, varscan2
- PRELID1 | c.381C>T p.R127= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100293476; called by muse, mutect2, varscan2
- PROX2 | c.135C>T p.V45= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV101507794; called by muse, mutect2
- QPRT | c.849C>T p.L283= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99568923; called by muse, mutect2, varscan2
- RASGRF2 | c.2880A>G p.E960= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV99428658; called by muse, mutect2, varscan2
- RGS22 | c.792G>A p.L264= | Silent (SNP) | VAF 94/260 reads (36%) | catalogued as rs1341593453, COSV100693028; called by muse, mutect2, varscan2
- ROBO2 | c.2112G>A p.K704= | Silent (SNP) | VAF 82/119 reads (69%) | catalogued as COSV59948895; called by muse, mutect2, varscan2
- RSPH3 | c.1227C>G p.L409= (on ENST00000252655; = p.L267= on NM_031924.8) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs762794026, COSV99396181, COSV99396241; called by muse, mutect2
- SALL3 | c.1515C>T p.P505= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs755937032, COSV101610054, COSV73305897; called by muse, mutect2, varscan2
- SCN2A | c.2578T>C p.L860= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV99330388; called by muse, mutect2, varscan2
- SCN5A | c.4923G>A p.K1641= (on ENST00000333535 / NM_198056.3; = p.K1640= on NM_000335.5) | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100346817; called by muse, mutect2, varscan2
- SERTM1 | c.300C>T p.S100= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100171254; called by muse, mutect2, varscan2
- SESTD1 | c.1551G>A p.L517= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV100090245; called by muse, mutect2, varscan2
- SGSM1 | c.2043C>T p.A681= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs769656823, COSV101240486; called by muse, mutect2, varscan2
- SHROOM1 | c.852C>T p.S284= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100166970; called by muse, mutect2, varscan2
- SIGLEC1 | c.3702G>A p.R1234= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV52460776, COSV99167597; called by muse, mutect2, varscan2
- SLC30A8 | c.975G>A p.R325= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as COSV69972881; called by muse, mutect2, varscan2
- SNRK | c.183C>T p.F61= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV56068454; called by muse, mutect2, varscan2
- SORCS2 | c.1371A>C p.A457= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100211723; called by muse, mutect2, varscan2
- TBX3 | c.669C>T p.F223= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57469779, COSV99983492; called by muse, mutect2, varscan2
- TECTA | c.2010C>T p.N670= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV99878915; called by muse, mutect2, varscan2
- ZNF334 | c.69A>G p.E23= | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as COSV100748989, COSV100749084; called by muse, mutect2, varscan2
- ZNF578 | c.1701C>T p.Y567= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV101405018; called by muse, mutect2, varscan2
- ZNRF3 | c.1560C>T p.H520= (on ENST00000544604 / NM_001206998.2; = p.H420= on NM_032173.3) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100238046; called by muse, mutect2, varscan2
- ZP3 | c.381C>T p.S127= (on ENST00000394857 / NM_001110354.2; = p.S76= on NM_007155.6) | Silent (SNP) | VAF 54/62 reads (87%) | catalogued as rs144953873; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24049332 G>A | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1152C>T | 3'UTR (SNP) | VAF 19/35 reads (54%) | catalogued as COSV53414183, COSV53419246; called by muse, mutect2, varscan2
- KIF1B | c.2115+6994C>T | Intron (SNP) | VAF 51/135 reads (38%) | catalogued as COSV55811021, COSV99822660; called by muse, mutect2, varscan2
- RCC1 | c.-261-706G>A | Intron (SNP) | VAF 36/100 reads (36%) | catalogued as rs1432370403, COSV63120549, COSV63120989; called by muse, mutect2, varscan2
- RCC1 | c.-261-705G>A | Intron (SNP) | VAF 37/100 reads (37%) | catalogued as rs1287822647, COSV100775625; called by muse, mutect2, varscan2
- SNORD48 | chr6:31835288 TGAGTGTGTCGCTGATGCCATCACCGCAGCGCTCTGACCG>GAGTGTGTCGCTGATGCCATCACCGCAGCGCTCTGACCGC | RNA (ONP) | VAF 8/72 reads (11%) | called by mutect2*, pindel, varscan2*
- WNK1 | c.2140-3107G>C | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as rs1381499821; called by muse, mutect2
